TCGA case TCGA-BR-8590 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d59824bd-816e-4ffc-8aae-1c3eff1f800e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 62 years; Vital status: Dead; Days to death: 284 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.1; Tissue or organ of origin: Fundus of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 62.8 years (22,937 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T4b; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 284 days.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 5; Lymph nodes tested: 7.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide + Fluorouracil; Days to treatment start: 42 days; Days to treatment end: 203 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 42 days; Days to treatment end: 203 days; Treatment outcome: Complete Response.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Lung, NOS. Age at diagnosis: 63.4 years (23,160 days); Days to diagnosis: 223 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Days to follow up: 65 days; Disease response: Tumor Free.
- Day 223 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 223 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 284 days; Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-8590-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.8; Intermediate dimension: 1.2; Shortest dimension: 0.3.
  Slide TCGA-BR-8590-01A-01-TS1: Section location: Top; Percent tumor cells: 62; Percent tumor nuclei: 65; Percent normal cells: 8; Percent necrosis: 0; Percent stromal cells: 30.
  Slide TCGA-BR-8590-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 30.
- Sample TCGA-BR-8590-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-8590-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Cancer procurement city: Tver.
- Drug treatment 2: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; New tumor event site: Lung; Treatment outcome first course: Complete Remission/Response; Cause of death: Stomach Cancer.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 284 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 284 days; disease-free interval: event (new tumor event after initially disease-free), 223 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 223 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-8590-01A-11D-2390-01): tumor purity 0.31, ploidy 3.8, whole-genome doublings 1.
